Somatic mutation profile of tumor specimen TCGA-J9-A8CM-01A (aliquot TCGA-J9-A8CM-01A-11D-A34U-08) from TCGA case TCGA-J9-A8CM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,118 days).
Specimen TCGA-J9-A8CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e8eb1c7-7572-40fd-be6c-bb7c2cb1b46b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A8CM-10A (Blood Derived Normal), aliquot TCGA-J9-A8CM-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53b137e8-0697-4134-b5e0-699c63bdec20

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, In Frame Del 3, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV99978084; called by muse, mutect2, varscan2
- ADAMTS18 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV99273791; called by muse, mutect2
- ANKRD26 | c.3511T>G p.F1171V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV101063345, COSV65778952; called by muse, mutect2, varscan2
- ATP10D | c.1255C>A p.Q419K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV99906028; called by muse, mutect2, varscan2
- ATP13A5 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV100665563; called by muse, mutect2, varscan2
- CA5A | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs745437622, COSV99990758; called by muse, mutect2, varscan2
- CARMIL1 | c.2426A>G p.E809G | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100278594; called by muse, mutect2, varscan2
- CCDC198 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as COSV99371356; called by muse, mutect2
- CCDC81 | c.1807G>A p.A603T (on ENST00000445632 / NM_001156474.2; = p.A513T on NM_021827.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.311); catalogued as rs144706705; called by muse, mutect2, varscan2
- DACH2 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100913728, COSV64187502; called by muse, mutect2, varscan2
- DDX39B | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100795263; called by muse, mutect2, varscan2
- DPP10 | c.1268G>T p.W423L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070443; called by muse, mutect2, varscan2
- EXOSC5 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV55371908, COSV99652731; called by muse, mutect2, varscan2
- FAM83C | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100981650; called by muse, mutect2, varscan2
- H4C11 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.662); catalogued as rs374472052, COSV61827472; called by mutect2, varscan2
- ISLR | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs764197388, COSV99997491; called by muse, mutect2, varscan2
- ITIH4 | c.885A>C p.E295D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.284); catalogued as COSV99819727; called by muse, mutect2, varscan2
- LINGO1 | c.1228T>A p.F410I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV100796479; called by muse, mutect2, varscan2
- LMOD2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs776758727, COSV101505463; called by muse, mutect2, varscan2
- MFSD2B | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as rs773308009, COSV100601190; called by muse, mutect2, varscan2
- MMP25 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100339575; called by muse, mutect2, varscan2
- MRC2 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV100316622; called by muse, varscan2
- MYH2 | c.3313G>T p.A1105S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV99820709; called by muse, mutect2, varscan2
- MYLK2 | c.1402A>G p.M468V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101044906; called by muse, mutect2, varscan2
- NOD1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs781740731, COSV99768412; called by muse, mutect2, varscan2
- OR5D13 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs375224277, COSV100686845; called by muse, mutect2, varscan2
- PARN | c.1780A>T p.T594S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100421264; called by muse, mutect2, varscan2
- PCDHA1 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1554118194, COSV100974425; called by muse, mutect2, varscan2
- PCDHGB6 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as rs573212606, COSV99544224; called by muse, mutect2, varscan2
- PDE8A | c.626T>A p.L209Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100052241; called by muse, mutect2
- PDK2 | c.271A>C p.S91R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50303415, COSV99143048; called by muse, varscan2
- PEX6 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99769936; called by muse, mutect2, varscan2
- PI4K2A | c.1095C>G p.Y365* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101034320; called by muse, mutect2, varscan2
- POTEH | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV100625169; called by muse, mutect2, varscan2
- PYM1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1351337808, COSV100212688, COSV56812060; called by muse, mutect2, varscan2
- RPRD1B | c.528+1G>T p.X176_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100987285; called by muse, mutect2, varscan2
- SDHC | c.405+2T>C p.X135_splice | Splice Site (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100713741; called by muse, mutect2, varscan2
- SIGLEC8 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV100367348; called by muse, mutect2, varscan2
- SNCAIP | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99749837; called by muse, mutect2, varscan2
- SORCS1 | c.1940+1G>A p.X647_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as rs1447669165, COSV53872995; called by muse, mutect2, varscan2
- TAF6 | c.1909C>A p.P637T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.029); catalogued as COSV100612836; called by muse, mutect2, varscan2
- TRANK1 | c.8092A>T p.T2698S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100084319; called by muse, mutect2, varscan2
- USP53 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as rs551730276, COSV99917980; called by muse, mutect2, varscan2
- WDR46 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs141256696; called by muse, mutect2, varscan2
- ZC3H11A | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100142623, COSV59746321; called by muse, mutect2, varscan2
- ZNF629 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354952; called by muse, mutect2, varscan2
- ZSWIM4 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1303965987, COSV99585305; called by muse, mutect2, varscan2
- BRCA2 | c.2746del p.C916Vfs*2 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.3687_3703del p.E1230Kfs*14 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- CUBN | c.8982_8990del p.F2995_T2997del | In Frame Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- DCST2 | c.642_653del p.D215_D218del | In Frame Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- IGHA1 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MYORG | c.977_1010del p.R326Pfs*97 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel
- SLFNL1 | c.123_164del p.E41_N55delinsD | In Frame Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel
- WHRN | c.1967dup p.A657Cfs*81 | Frame Shift Ins (INS) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- ACTA1 | c.174C>T p.D58= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100796785; called by muse, mutect2, varscan2
- ADGRG3 | c.1044C>T p.F348= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs368898879; called by muse, mutect2, varscan2
- AOC3 | c.1263C>G p.A421= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99520333; called by muse, mutect2, varscan2
- APOC3 | c.126C>A p.T42= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52637034, COSV52637162, COSV99369350; called by muse, mutect2, varscan2
- BAIAP2L2 | c.342C>T p.F114= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV60201675; called by muse, mutect2, varscan2
- CDK5 | c.42C>G p.T14= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV99877274; called by muse, mutect2, varscan2
- EOMES | c.1074T>A p.T358= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs1198559671, COSV99842193; called by muse, mutect2, varscan2
- KIR2DL3 | c.579A>C p.G193= | Silent (SNP) | VAF 95/285 reads (33%) | catalogued as COSV100668029; called by muse, mutect2, varscan2
- KNSTRN | c.102T>C p.F34= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs540599208, COSV99991977; called by muse, mutect2, varscan2
- LHX4 | c.378G>C p.T126= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV55372599, COSV99761795; called by muse, mutect2, varscan2
- NDEL1 | c.345G>T p.V115= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100233201; called by muse, mutect2, varscan2
- NPTX2 | c.984C>T p.D328= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs781445701, COSV55719214; called by mutect2, varscan2
- NTNG2 | c.804G>T p.R268= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100647665; called by muse, mutect2, varscan2
- OR5A2 | c.852C>T p.P284= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs150394868, COSV100119798, COSV100119827; called by muse, mutect2, varscan2
- POU6F2 | c.1494T>A p.L498= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101302811; called by muse, mutect2, varscan2
- PTPRC | c.2652T>C p.Y884= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs765838909, COSV100722985; called by muse, mutect2, varscan2
- RSBN1 | c.2182C>A p.R728= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV99793515; called by muse, mutect2, varscan2
- SMOC1 | c.954G>A p.G318= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100734755; called by muse, mutect2, varscan2
- TEX29 | c.43C>T p.L15= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99366162; called by muse, mutect2, varscan2
- USH2A | c.5181T>A p.L1727= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV100240302, COSV56386594; called by muse, mutect2, varscan2
- MIR548M | n.42A>T | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
